CCDI case PBCIJW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/78ee7bfd-f7f5-4f34-b2b0-59df481f915c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.1 years (3,674 days).

Biospecimens (3 samples)
- Sample 0DU3KB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3KU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DU3ME: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
